Somatic mutation profile of tumor specimen MP2PRT-PARTSD-TMP1-A (aliquot MP2PRT-PARTSD-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PARTSD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,209 days).
Specimen MP2PRT-PARTSD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcc75e7d-0e92-4d60-94f4-3d598be0064f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTSD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTSD-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d2f75d1-feae-4d99-8ecf-d8f67caa341c

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC099489.1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as rs1360957505; called by muse, mutect2, varscan2
- ARSI | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 154/461 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs149628658; called by muse, mutect2, varscan2
- KMT2D | c.8062G>C p.E2688Q | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV56418872; called by muse, mutect2
- MINAR1 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 156/348 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs147416682; called by muse, mutect2, varscan2
- MYSM1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs958860111; called by muse, mutect2
- PSD2 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 188/477 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs147042685, COSV51198737; called by muse, mutect2, varscan2
- TLL1 | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs760021584, COSV50262509; called by muse, mutect2, varscan2
- TNFRSF11B | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 151/358 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375274060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH7 | c.1379C>A p.P460Q | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by mutect2, varscan2
- DEPDC1 | c.1943A>G p.H648R (on ENST00000456315 / NM_001114120.3; = p.H364R on NM_017779.6) | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4K17 | c.899A>G p.K300R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- PCDHGC3 | c.1396A>C p.I466L | Missense Mutation (SNP) | VAF 22/443 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- SHISAL2A | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 21/637 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); called by muse, mutect2
- TXNRD3 | c.1445A>G p.D482G | Missense Mutation (SNP) | VAF 13/432 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ACOX2 | c.315C>T p.Y105= | Silent (SNP) | VAF 112/272 reads (41%) | catalogued as rs146624586; called by muse, mutect2, varscan2
- CYP11B1 | c.447G>T p.L149= | Silent (SNP) | VAF 20/591 reads (3%) | called by muse, mutect2
- MMRN2 | c.1647G>A p.A549= | Silent (SNP) | VAF 284/625 reads (45%) | catalogued as rs1211415444; called by muse, mutect2, varscan2
- PER2 | c.2118C>T p.G706= | Silent (SNP) | VAF 24/494 reads (5%) | catalogued as COSV54524829, COSV54526848; called by muse, mutect2
- MTF2 | c.-223G>A | 5'UTR (SNP) | VAF 18/436 reads (4%) | called by muse, mutect2
